TCGA case TCGA-B0-5694 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/11111b58-c7df-4291-ad8a-4baec9ff7d1f

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 71 years; Vital status: Dead; Days to death: 480 days (1.3 years).

Diagnoses (3)
1. Clear cell adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 71.3 years (26,060 days); Year of diagnosis: 2008; AJCC pathologic T: T3a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Tumor grade: G3; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Progressive Disease; Days to treatment start: 399 days (1.1 years); Days to treatment end: 410 days (1.1 years); Treatment dose: 2,700 cGy; Number of fractions: 9; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pazopanib; Days to treatment start: 441 days (1.2 years); Days to treatment end: 469 days (1.3 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Radiation, Cyberknife; Initial disease status: Progressive Disease; Days to treatment start: 469 days (1.3 years); Days to treatment end: 469 days (1.3 years); Treatment anatomic sites: Distant Site.
2. Squamous cell carcinoma, clear cell type: ICD-O-3 morphology code: 8084/3; Tissue or organ of origin: Lung, NOS; Laterality: Bilateral; Classification of tumor: Synchronous primary.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 72.1 years (26,348 days); Days to diagnosis: 288 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Surgery, NOS to Locoregional Site; Surgery, NOS to Distant Site.

Follow-up (2 entries)
- Day 288 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 480 days (1.3 years); Disease response: With Tumor.

Molecular and laboratory tests
- Platelets: Low.
- Calcium: Low.
- Leukocytes: Normal.
- Hemoglobin: Low.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-B0-5694-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 2.5; Intermediate dimension: 1.5; Shortest dimension: 0.3.
  Slide TCGA-B0-5694-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5.
  Slide TCGA-B0-5694-01A-01-BS1: Section location: Bottom; Percent tumor cells: 95; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5.
- Sample TCGA-B0-5694-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-B0-5694-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.2; Intermediate dimension: 0.6; Shortest dimension: 0.2.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Serum calcium level: Low; Hemoglobin level: Low; Lymph nodes examined: No.
- Drug treatment: Treatment best response: Clinical Progressive Disease.
- Radiation treatment 1: Radiation type other: Cyberknife; Therapy regimen: Progression.
- Follow-up form: New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: No.
- Other malignancy form: Malignancy type: Synchronous Malignancy; Other malignancy anatomic site: Lung; Other malignancy laterality: Both; Other malignancy histological type: Lung Clear Cell Squamous Cell Carcinoma.

GDC annotations on this case (curator notes; quoted as recorded):
- Synchronous malignancy: Pt with synchronous bilateral LUSC.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 480 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 480 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 288 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-B0-5694-01A-11D-1530-01): tumor purity 0.65, ploidy 2.01, whole-genome doublings 0.
